Somatic mutation profile of tumor specimen TCGA-EB-A3HV-01A (aliquot TCGA-EB-A3HV-01A-11D-A21A-08) from TCGA case TCGA-EB-A3HV, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 37.5 years (13,712 days).
Specimen TCGA-EB-A3HV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c995b19e-eb59-40ad-ba1c-82db843d49d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A3HV-10B (Blood Derived Normal), aliquot TCGA-EB-A3HV-10B-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68d2fba2-c453-42e9-88c5-84cd227bb505

The open-access MAF lists 55 somatic variants for this specimen: 36 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 18, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/167 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADGRB3 | c.2618C>T p.S873F | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.024); catalogued as rs1172908365, COSV53237270; called by muse, mutect2, varscan2
- AHNAK | c.7832C>T p.P2611L | Missense Mutation (SNP) | VAF 99/268 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57206012; called by muse, mutect2, varscan2
- CALCRL | c.457A>T p.I153F | Missense Mutation (SNP) | VAF 12/416 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV66473921; called by muse, mutect2
- CHD8 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.025); catalogued as rs757770866, COSV67869869; called by muse, mutect2, varscan2
- CRYBB2 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.297); catalogued as COSV68005334; called by muse, mutect2, varscan2
- ELN | c.2051G>C p.G684A (on ENST00000320399 / NM_001278939.1; = p.G651A on NM_000501.4) | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV52707899; called by muse, mutect2, varscan2
- EYA2 | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV57939729; called by muse, mutect2, varscan2
- EYA4 | c.1076G>A p.G359E (on ENST00000531901 / NM_001301013.1; = p.G353E on NM_004100.5) | Missense Mutation (SNP) | VAF 83/254 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs267600817, COSV62047346; called by muse, mutect2, varscan2
- KHDRBS2 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV55432335; called by muse, mutect2, varscan2
- KRT4 | c.962G>A p.R321K | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs779551294, COSV53406089, COSV99543040; called by muse, mutect2, varscan2
- MAGI2 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.197); catalogued as COSV62639347; called by muse, mutect2, varscan2
- MISP | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV53119163; called by muse, mutect2, varscan2
- MYL12B | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs776870278, COSV52898274; called by muse, mutect2, varscan2
- NCAN | c.553A>G p.S185G | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs370349783; called by muse, mutect2, varscan2
- NDUFAF5 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV65246605; called by muse, mutect2, varscan2
- NLRP5 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 105/338 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537471101, COSV66762321; called by muse, mutect2, varscan2
- NOX4 | c.1616G>A p.G539E | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV54448559; called by muse, mutect2, varscan2
- NWD1 | c.1817A>C p.D606A | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60338696; called by muse, mutect2, varscan2
- OR2T1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822237, COSV63541456; called by muse, mutect2, varscan2
- PGM3 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV99382126; called by muse, mutect2, varscan2
- PGM3 | c.1618C>G p.P540A | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); catalogued as COSV99382128; called by muse, mutect2, varscan2
- PIK3R1 | c.1924C>T p.R642* (on ENST00000521381 / NM_181523.3; = p.R372* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 11/264 reads (4%) | catalogued as rs1419325070, COSV57123056; called by muse, mutect2
- PITPNM3 | c.2415G>A p.M805I | Missense Mutation (SNP) | VAF 124/414 reads (30%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.5); catalogued as COSV52593503; called by muse, mutect2, varscan2
- PLA2G4C | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 119/331 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.739); catalogued as COSV62784267; called by muse, mutect2, varscan2
- PRPF19 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1335005545, COSV57126892; called by muse, mutect2, varscan2
- SGSM1 | c.2359C>A p.L787M (on ENST00000400359 / NM_001039948.4; = p.L726M on NM_133454.3) | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as COSV63082316, COSV63082708; called by muse, mutect2, varscan2
- SLC29A3 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.29); catalogued as rs770328093; called by mutect2, varscan2
- SLC9B1 | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 33/293 reads (11%) | catalogued as COSV56467872, COSV56469127; called by muse, mutect2, varscan2
- TBCCD1 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.161); catalogued as COSV58661712; called by muse, mutect2, varscan2
- TBX5 | c.977G>A p.R326K | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV59858989; called by muse, mutect2, varscan2
- TSPAN32 | c.739C>A p.Q247K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV51718964; called by muse, mutect2, varscan2
- TTLL7 | c.670G>T p.G224W | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53082062; called by muse, mutect2, varscan2
- TTN | c.35386G>A p.E11796K (on ENST00000591111; = p.E10869K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | PolyPhen probably damaging (0.987); catalogued as COSV59924290, COSV60210845; called by muse, mutect2, varscan2
- UMODL1 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61159490; called by muse, mutect2
- ZNF619 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs764070183, COSV59029522; called by muse, mutect2, varscan2
- AC100868.1 | c.1587C>T p.S529= | Silent (SNP) | VAF 59/153 reads (39%) | catalogued as COSV51839348; called by muse, mutect2, varscan2
- ACSBG1 | c.1083G>A p.V361= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as COSV51903905; called by muse, mutect2, varscan2
- AR | c.2295C>T p.F765= | Silent (SNP) | VAF 25/30 reads (83%) | catalogued as rs369390411, CM921035, COSV65953823; called by muse, mutect2, varscan2
- ARID1A | c.5796C>T p.A1932= | Silent (SNP) | VAF 155/226 reads (69%) | catalogued as COSV61373213; called by muse, mutect2, varscan2
- ARSJ | c.1173G>A p.Q391= | Silent (SNP) | VAF 114/212 reads (54%) | catalogued as rs1477460901, COSV59537010; called by muse, mutect2, varscan2
- CD163 | c.486G>A p.T162= | Silent (SNP) | VAF 144/436 reads (33%) | catalogued as rs138586891; called by muse, mutect2, varscan2
- CREB3L3 | c.1242G>A p.S414= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs1568286651, COSV50176175; called by muse, mutect2, varscan2
- ELMO3 | c.222C>T p.L74= (on ENST00000652269; = p.L21= on NM_024712.5) | Silent (SNP) | VAF 86/259 reads (33%) | catalogued as rs1310018158, COSV62606042; called by muse, mutect2, varscan2
- HYLS1 | c.742C>A p.R248= | Silent (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- INTS1 | c.1680C>A p.A560= | Silent (SNP) | VAF 49/139 reads (35%) | catalogued as COSV67176620, COSV67178931; called by muse, mutect2, varscan2
- LAMA3 | c.6963G>A p.G2321= (on ENST00000313654 / NM_198129.4; = p.G712= on NM_000227.6) | Silent (SNP) | VAF 39/144 reads (27%) | catalogued as rs1221471897, COSV52530939; called by muse, mutect2, varscan2
- MOCOS | c.1452C>T p.F484= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV54341654; called by muse, mutect2
- PRPH2 | c.96C>T p.I32= | Silent (SNP) | VAF 70/179 reads (39%) | catalogued as COSV57836372; called by muse, mutect2, varscan2
- PTPRT | c.2667C>T p.F889= | Silent (SNP) | VAF 45/137 reads (33%) | catalogued as COSV61965949; called by muse, mutect2, varscan2
- RAD51AP2 | c.729G>A p.L243= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV67587506; called by muse, mutect2, varscan2
- TNK2 | c.672C>T p.F224= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV57366681; called by muse, mutect2, varscan2
- TTLL6 | c.1062G>A p.R354= (on ENST00000393382 / NM_001130918.3; = p.R47= on NM_173623.3) | Silent (SNP) | VAF 47/171 reads (27%) | catalogued as rs1194689450, COSV64976522; called by muse, mutect2, varscan2
- VIT | c.96G>A p.K32= | Silent (SNP) | VAF 51/140 reads (36%) | catalogued as COSV64895591; called by muse, mutect2, varscan2
- DST | c.4297-3558A>G | Intron (SNP) | VAF 84/249 reads (34%) | catalogued as COSV99757067; called by muse, mutect2
